Somatic mutation profile of tumor specimen TCGA-E7-A8O8-01A (aliquot TCGA-E7-A8O8-01A-11D-A364-08) from TCGA case TCGA-E7-A8O8, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 59.2 years (21,629 days).
Specimen TCGA-E7-A8O8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5c77cfc1-d56b-413d-b5e3-00578333fa76.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E7-A8O8-10A (Blood Derived Normal), aliquot TCGA-E7-A8O8-10A-01D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/87ac25f3-698b-40d5-a8b2-d19bbfdfca5c

The open-access MAF lists 131 somatic variants for this specimen: 102 protein-altering or splice-affecting, 25 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 79, Silent 25, Nonsense Mutation 13, Frame Shift Del 5, Splice Site 2, Frame Shift Ins 1, RNA 1, In Frame Del 1, 3'UTR 1, Intron 1, 3'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.3747-1G>C p.X1249_splice | Splice Site (SNP) | VAF 27/35 reads (77%) | catalogued as rs730881364, CS122160, COSV53724665, COSV53726690; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- HRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 32/48 reads (67%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as rs121913233, COSV54236656, COSV54236691, COSV54238654; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.176C>G p.A59G | Missense Mutation (SNP) | VAF 27/55 reads (49%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.418); catalogued as COSV55568979, COSV55604554, COSV55904854; called by muse, mutect2, varscan2
- SCN9A | c.1198G>A p.V400M | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1553491169, CM093842, COSV57620397; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADGRF5 | c.1716G>A p.M572I | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT tolerated (0.18); PolyPhen benign (0.052); catalogued as COSV51938599; called by muse, mutect2, varscan2
- AFDN | c.3512G>A p.R1171H | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.724); catalogued as rs766388839, COSV60053130; called by muse, mutect2, varscan2
- ALB | c.1324G>A p.V442M | Missense Mutation (SNP) | VAF 39/57 reads (68%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.975); catalogued as rs1257438609, COSV55741343; called by muse, mutect2, varscan2
- AMY2A | c.605T>G p.I202S | Missense Mutation (SNP) | VAF 149/365 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs1367689036, COSV70214824; called by muse, mutect2, varscan2
- ARL6IP5 | c.226G>A p.V76M | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as rs767854308, COSV56235526; called by muse, mutect2, varscan2
- ATR | c.4346A>T p.H1449L | Missense Mutation (SNP) | VAF 54/112 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.301); catalogued as COSV63390320; called by muse, mutect2, varscan2
- B3GNT4 | c.793T>A p.S265T | Missense Mutation (SNP) | VAF 34/59 reads (58%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.828); catalogued as COSV57337197; called by muse, mutect2, varscan2
- CACNG3 | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 23/35 reads (66%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as rs1325822639, COSV50063788, COSV50074688; called by muse, mutect2, varscan2
- CARM1 | c.848G>A p.G283E | Missense Mutation (SNP) | VAF 53/58 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59002655; called by muse, mutect2, varscan2
- CCND1 | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs747703578, COSV57122822; called by muse, mutect2, varscan2
- CDCA7L | c.411_413del p.R137del | In Frame Del (DEL) | VAF 26/64 reads (41%) | catalogued as rs761733292; called by pindel, varscan2
- CHST13 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs779610571, COSV60042989; called by muse, mutect2, varscan2
- CNGA3 | c.1271T>C p.M424T | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV55627192; called by muse, mutect2, varscan2
- CNTN6 | c.3028C>A p.H1010N | Missense Mutation (SNP) | VAF 47/76 reads (62%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV63185114; called by muse, mutect2, varscan2
- COMP | c.453C>A p.C151* | Nonsense Mutation (SNP) | VAF 8/14 reads (57%) | catalogued as rs201389713, COSV99721499; called by muse, varscan2
- CST2 | c.358T>C p.F120L | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100491257; called by muse, mutect2
- CTTNBP2 | c.4333T>A p.C1445S | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as COSV50451640; called by muse, mutect2, varscan2
- CYP3A5 | c.817C>A p.Q273K | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as COSV56122231; called by muse, mutect2, varscan2
- CYP3A5 | c.652C>G p.P218A | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV56119467; called by muse, mutect2, varscan2
- DDHD2 | c.1693C>T p.H565Y | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.928); catalogued as COSV68158530; called by muse, mutect2, varscan2
- DDX21 | c.953G>T p.R318L | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV100826531; called by muse, mutect2
- DLC1 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 77/83 reads (93%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.051); catalogued as rs770997237, COSV52321718; called by muse, mutect2, varscan2
- DNAH3 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 44/73 reads (60%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs759657387, COSV51786493; called by muse, mutect2, varscan2
- DPP8 | c.593C>T p.T198M (on ENST00000341861 / NM_001320875.2; = p.T182M on NM_017743.6) | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0.01); catalogued as rs200120025, COSV55682153; called by muse, mutect2, varscan2
- EDIL3 | c.239del p.P80Lfs*12 | Frame Shift Del (DEL) | VAF 19/38 reads (50%) | catalogued as COSV99677288; called by mutect2, pindel, varscan2
- EDRF1 | c.2087A>G p.Y696C (on ENST00000356792 / NM_001202438.2; = p.Y662C on NM_015608.2) | Missense Mutation (SNP) | VAF 52/109 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs759674791, COSV61765767; called by muse, mutect2, varscan2
- ENPP5 | c.691C>G p.L231V | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT tolerated (0.84); PolyPhen benign (0.006); catalogued as rs1263530074, COSV100040194, COSV57909674; called by muse, mutect2, varscan2
- EPS15 | c.2033A>G p.N678S | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs138350324; called by muse, mutect2, varscan2
- ERAL1 | c.41C>T p.S14L | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as rs765193376, COSV54740711; called by muse, mutect2, varscan2
- FAM83D | c.949C>T p.R317* | Nonsense Mutation (SNP) | VAF 5/87 reads (6%) | catalogued as rs911477186, COSV54158383; called by muse, mutect2
- FAP | c.236A>T p.Y79F | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.93); PolyPhen benign (0.007); catalogued as COSV51866088; called by muse, mutect2, varscan2
- FREM2 | c.7441G>A p.A2481T | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as rs759338792, COSV54847884; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FRY | c.1924_1945del p.H642Rfs*26 | Frame Shift Del (DEL) | VAF 16/94 reads (17%) | catalogued as COSV66576757; called by mutect2, pindel, varscan2
- GAK | c.2333C>G p.S778C | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as rs1260189188, COSV58508372; called by muse, mutect2, varscan2
- GLI2 | c.1853A>T p.Q618L (on ENST00000361492 / NM_001374353.1; = p.Q635L on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV58049018; called by muse, mutect2, varscan2
- GRK7 | c.178T>G p.C60G | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53824732; called by muse, mutect2, varscan2
- HERC1 | c.6112G>T p.E2038* | Nonsense Mutation (SNP) | VAF 14/126 reads (11%) | catalogued as COSV101496698; called by muse, mutect2, varscan2
- HRNR | c.457G>T p.E153* | Nonsense Mutation (SNP) | VAF 58/150 reads (39%) | catalogued as COSV100913646; called by muse, mutect2, varscan2
- ITGA4 | c.2555G>A p.C852Y | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101223492; called by muse, mutect2
- KANK1 | c.3005G>T p.G1002V | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV63214455; called by muse, mutect2
- KDM6A | c.3285-2A>T p.X1095_splice | Splice Site (SNP) | VAF 18/18 reads (100%) | catalogued as COSV65044141; called by muse, mutect2, varscan2
- KMT2C | c.6160C>T p.Q2054* | Nonsense Mutation (SNP) | VAF 28/66 reads (42%) | catalogued as COSV51417694, COSV51450906; called by muse, mutect2, varscan2
- LIG4 | c.2444G>A p.R815H | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs574090677, COSV63597369; called by muse, mutect2, varscan2
- LRRC40 | c.1758G>C p.M586I | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV63943084; called by muse, mutect2, varscan2
- LRRK2 | c.3178A>G p.I1060V | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs895587694, COSV54165483; called by muse, mutect2, varscan2
- MAPK8IP2 | c.1839C>T p.F613= | Splice Region (SNP) | VAF 12/17 reads (71%) | catalogued as COSV50506614; called by muse, mutect2, varscan2
- MARK3 | c.1138A>T p.S380C | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV53514557; called by muse, mutect2, varscan2
- MCTP1 | c.2578G>C p.D860H | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV56529147; called by muse, mutect2, varscan2
- MGAM | c.3265A>T p.K1089* | Nonsense Mutation (SNP) | VAF 37/76 reads (49%) | catalogued as COSV101527580; called by muse, mutect2, varscan2
- MIPOL1 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as rs1265781623, COSV59391080; called by muse, mutect2, varscan2
- MYH4 | c.4842T>A p.D1614E | Missense Mutation (SNP) | VAF 79/139 reads (57%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV55124038; called by muse, mutect2, varscan2
- MYSM1 | c.796G>A p.D266N | Missense Mutation (SNP) | VAF 64/142 reads (45%) | SIFT tolerated (0.49); PolyPhen benign (0.014); catalogued as COSV68978131; called by muse, varscan2
- NEB | c.15967C>T p.H5323Y | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV99425044; called by muse, mutect2
- NUMA1 | c.5680G>A p.G1894R | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV52622341; called by muse, mutect2, varscan2
- ODAPH | c.139A>T p.T47S | Missense Mutation (SNP) | VAF 53/77 reads (69%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV61141548; called by muse, mutect2, varscan2
- OR2F1 | c.676C>A p.L226I | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.204); catalogued as COSV67331640; called by muse, mutect2, varscan2
- OR5K2 | c.508G>T p.G170* | Nonsense Mutation (SNP) | VAF 21/200 reads (11%) | catalogued as COSV101415973; called by muse, mutect2, varscan2
- PAX5 | c.809T>A p.L270Q | Missense Mutation (SNP) | VAF 32/57 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV63911529; called by muse, mutect2, varscan2
- PCDH15 | c.3406G>A p.D1136N | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1298520846, COSV57372502, COSV57380811, COSV57404150; called by muse, mutect2, varscan2
- PCDHA8 | c.1681A>T p.N561Y | Missense Mutation (SNP) | VAF 67/107 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV65331233; called by muse, mutect2, varscan2
- PDE3B | c.1201C>G p.L401V | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.058); catalogued as COSV56388983; called by muse, mutect2, varscan2
- PENK | c.319T>A p.Y107N | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59242818, COSV59243253; called by muse, mutect2, varscan2
- PHF24 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.169); catalogued as COSV54276268; called by muse, mutect2, varscan2
- PLEKHA5 | c.2650A>G p.R884G | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs761716705, COSV54710079; called by muse, mutect2, varscan2
- PPP2R5B | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs150933072, COSV51209647; called by muse, mutect2, varscan2
- PRAMEF17 | c.1340C>A p.P447H | Missense Mutation (SNP) | VAF 17/189 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs749562253; called by muse, mutect2
- PTGES3L-AARSD1 | c.1078G>A p.E360K (on ENST00000421990 / NM_001136042.2; = p.E342K on NM_025267.3) | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64184210; called by muse, mutect2, varscan2
- PXDN | c.3150C>G p.Y1050* | Nonsense Mutation (SNP) | VAF 5/14 reads (36%) | catalogued as rs1462193700, COSV99414113; called by muse, mutect2, varscan2
- PZP | c.844G>T p.V282F | Missense Mutation (SNP) | VAF 53/140 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs1214421653, COSV54367926; called by muse, mutect2, varscan2
- RBPMS2 | c.143A>T p.Y48F | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV55605608; called by muse, mutect2, varscan2
- RELN | c.4246T>G p.C1416G | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV59027113; called by muse, mutect2, varscan2
- RFTN2 | c.265C>T p.R89* | Nonsense Mutation (SNP) | VAF 8/172 reads (5%) | catalogued as rs1164246651, COSV54388642; called by muse, mutect2
- RNF213 | c.6136C>T p.Q2046* | Nonsense Mutation (SNP) | VAF 3/24 reads (13%) | catalogued as COSV100301044; called by muse, mutect2
- SEC14L5 | c.1897G>A p.D633N | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.223); catalogued as rs781520324, COSV52040993; called by muse, mutect2, varscan2
- SIN3A | c.1282C>T p.R428C | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1023368225, COSV64584415; called by muse, mutect2, varscan2
- SKIV2L | c.2240C>T p.T747M | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752777790, COSV61714737; called by muse, mutect2, varscan2
- SLC29A3 | c.1349G>C p.G450A | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.898); catalogued as COSV64385917, COSV64386020; called by muse, mutect2, varscan2
- SLC6A11 | c.1297G>A p.G433S | Missense Mutation (SNP) | VAF 169/231 reads (73%) | SIFT tolerated (0.25); PolyPhen benign (0.129); catalogued as COSV54397572; called by muse, mutect2, varscan2
- SNRNP200 | c.1669A>G p.K557E | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.13); PolyPhen benign (0.081); catalogued as COSV60493356; called by muse, mutect2, varscan2
- SPN | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT tolerated (0.07); PolyPhen benign (0.198); catalogued as rs373798010, COSV64070645; called by muse, mutect2, varscan2
- SRSF1 | c.397A>T p.S133C | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51966184; called by muse, mutect2, varscan2
- STAG2 | c.573A>G p.I191M | Missense Mutation (SNP) | VAF 169/179 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV54369114; called by muse, mutect2, varscan2
- TAF1L | c.2264C>G p.P755R | Missense Mutation (SNP) | VAF 85/209 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV54266999; called by muse, mutect2, varscan2
- TMEM8B | c.982G>T p.G328* | Nonsense Mutation (SNP) | VAF 12/233 reads (5%) | catalogued as COSV100941658; called by muse, mutect2
- TTC3 | c.1486G>C p.D496H | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749731110, COSV61294713; called by muse, mutect2, varscan2
- UBASH3B | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 21/28 reads (75%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs377346539; called by muse, mutect2, varscan2
- UBR5 | c.5278A>G p.T1760A | Missense Mutation (SNP) | VAF 4/92 reads (4%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV99641452; called by muse, mutect2
- VCAM1 | c.986A>G p.D329G | Missense Mutation (SNP) | VAF 50/105 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0.042); catalogued as COSV54121230; called by muse, mutect2, varscan2
- ZBTB11 | c.1144C>T p.R382* | Nonsense Mutation (SNP) | VAF 6/74 reads (8%) | catalogued as rs1452602541, COSV100465590; called by muse, mutect2
- ZFPM2 | c.2524C>T p.R842W | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as rs374720145, COSV101023173; called by muse, mutect2, varscan2
- ZNF423 | c.3691G>C p.E1231Q (on ENST00000563137 / NM_001379286.1; = p.E1223Q on NM_015069.4) | Missense Mutation (SNP) | VAF 44/63 reads (70%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.759); catalogued as COSV52200768; called by muse, mutect2, varscan2
- ZNF639 | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.98); catalogued as COSV58384095; called by muse, mutect2, varscan2
- ZNF700 | c.1898C>G p.S633* | Nonsense Mutation (SNP) | VAF 85/89 reads (96%) | catalogued as COSV54311954; called by muse, mutect2, varscan2
- CASR | c.2750_2751del p.H917Pfs*54 (on ENST00000490131; = p.H994Pfs*54 on NM_000388.4) | Frame Shift Del (DEL) | VAF 13/25 reads (52%) | called by mutect2, pindel, varscan2
- GATA3 | c.1209_1219del p.S404Afs*99 | Frame Shift Del (DEL) | VAF 16/57 reads (28%) | called by mutect2, pindel, varscan2
- MCOLN3 | c.908dup p.C303Wfs*3 | Frame Shift Ins (INS) | VAF 26/151 reads (17%) | called by mutect2, pindel, varscan2
- MYOF | c.3958del p.Q1320Rfs*23 | Frame Shift Del (DEL) | VAF 22/68 reads (32%) | called by mutect2, pindel, varscan2
- TRBV3-1 | c.215A>T p.E72V | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- ADAMTS18 | c.1533A>T p.P511= | Silent (SNP) | VAF 33/93 reads (35%) | catalogued as COSV51421258; called by muse, mutect2, varscan2
- APOBEC3A | c.189C>A p.L63= | Silent (SNP) | VAF 37/85 reads (44%) | catalogued as COSV99970367; called by muse, mutect2, varscan2
- ARID5B | c.3237A>T p.P1079= | Silent (SNP) | VAF 34/61 reads (56%) | catalogued as COSV54427488; called by muse, mutect2, varscan2
- CACNA1H | c.7041T>C p.G2347= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as rs774132789, COSV99326866; called by muse, mutect2, varscan2
- CDHR1 | c.633C>T p.V211= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as rs767268640, COSV60565547; called by muse, mutect2, varscan2
- GRIA4 | c.171G>T p.A57= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as COSV56913969; called by muse, mutect2, varscan2
- HERC1 | c.6111G>T p.P2037= | Silent (SNP) | VAF 14/126 reads (11%) | catalogued as COSV71249630; called by muse, mutect2, varscan2
- KDM2A | c.2877C>T p.L959= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV58191159; called by muse, mutect2, varscan2
- KLHL34 | c.783G>A p.T261= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as rs970499084, COSV65279691; called by muse, mutect2
- OR10G4 | c.435C>T p.T145= | Silent (SNP) | VAF 104/191 reads (54%) | catalogued as rs144654389, COSV57978418; called by muse, mutect2, varscan2
- PCDH11X | c.2358G>A p.V786= | Silent (SNP) | VAF 102/108 reads (94%) | catalogued as COSV53494767; called by muse, mutect2, varscan2
- PGAP1 | c.2214C>T p.V738= | Silent (SNP) | VAF 18/68 reads (26%) | catalogued as COSV61328717; called by muse, mutect2, varscan2
- PNLIP | c.111G>T p.T37= | Silent (SNP) | VAF 26/67 reads (39%) | catalogued as COSV65040959, COSV65041697; called by muse, mutect2, varscan2
- PRAMEF17 | c.1341C>G p.P447= | Silent (SNP) | VAF 16/186 reads (9%) | catalogued as rs768813100; called by muse, mutect2
- PTGES3L-AARSD1 | c.1218G>A p.V406= (on ENST00000421990 / NM_001136042.2; = p.V388= on NM_025267.3) | Silent (SNP) | VAF 19/43 reads (44%) | catalogued as COSV64184191; called by muse, mutect2, varscan2
- RGS9 | c.1833G>A p.V611= | Silent (SNP) | VAF 48/92 reads (52%) | catalogued as rs1236185546, COSV52228144; called by muse, mutect2, varscan2
- SOX6 | c.1299A>T p.T433= (on ENST00000528429 / NM_001145819.2; = p.T392= on NM_017508.3) | Silent (SNP) | VAF 40/134 reads (30%) | catalogued as COSV57054829; called by muse, mutect2, varscan2
- SPNS1 | c.1380G>C p.L460= | Silent (SNP) | VAF 27/38 reads (71%) | catalogued as COSV57956314; called by muse, mutect2, varscan2
- TKFC | c.393G>A p.P131= | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as rs779671347, COSV67523991; called by muse, mutect2, varscan2
- TMEM132D | c.936C>T p.S312= | Silent (SNP) | VAF 19/38 reads (50%) | catalogued as COSV70619065; called by muse, mutect2, varscan2
- TOX2 | c.780G>A p.S260= (on ENST00000358131 / NM_001098798.2; = p.S209= on NM_032883.3) | Silent (SNP) | VAF 39/54 reads (72%) | catalogued as rs756833543, COSV57893141; called by muse, mutect2, varscan2
- TTN | c.87315T>C p.D29105= (on ENST00000591111; = p.D21681= on NM_003319.4) | Silent (SNP) | VAF 38/69 reads (55%) | catalogued as rs375738563; called by muse, mutect2, varscan2
- TTN | c.3867T>A p.V1289= (on ENST00000591111; = p.V1243= on NM_003319.4) | Silent (SNP) | VAF 22/45 reads (49%) | catalogued as COSV60267191; called by muse, mutect2, varscan2
- ZKSCAN3 | c.27A>T p.T9= | Silent (SNP) | VAF 40/81 reads (49%) | catalogued as COSV52852298; called by muse, mutect2, varscan2
- ZNF329 | c.177T>G p.T59= | Silent (SNP) | VAF 63/174 reads (36%) | catalogued as COSV63773184; called by muse, mutect2, varscan2
- ADGRA1 | c.4-3795A>T | Intron (SNP) | VAF 6/15 reads (40%) | catalogued as COSV66929505; called by muse, mutect2, varscan2
- ATP6AP1L | n.1463C>T | RNA (SNP) | VAF 49/78 reads (63%) | catalogued as COSV66475443; called by muse, mutect2, varscan2
- FAS | c.*136A>T | 3'UTR (SNP) | VAF 50/84 reads (60%) | catalogued as COSV58239758; called by muse, mutect2, varscan2
- MYADM | chr19:53874345 G>T | 3'Flank (SNP) | VAF 22/72 reads (31%) | catalogued as COSV61240664; called by muse, mutect2, varscan2
